Surgical pathology report (de-identified scan), TCGA case TCGA-56-8307, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-8307-01A (Primary Tumor).

[page 1 of 4]
Results

GROSS AND MICROSCOPIC SURGICAL PANEL

Specimen Information

DIAGNOSIS

- A) LYMPH NODE, 4R, BIOPSY:
Fragmented lymph node, negative for neoplasm (0/1)
- B) LYMPH NODE, LEVEL 7, BIOPSY:
One lymph node, negative for neoplasm (0/1)
- C) LYMPH NODES, LEVEL 7, DISSECTION:
Two lymph nodes, negative for neoplasm (0/2)
- D) LYMPH NODE, 11R, DISSECTION:
One lymph node, negative for neoplasm (0/1)
- E) LUNG, RIGHT LOWER LOBE, RESECTION:
- Poorly differentiated squamous carcinoma, featuring:
- Size: 13 x 11.5 x 8.5 cm
- Margins: Negative for neoplasm
- Angiolymphatic invasion: Absent
- Extent of invasion: Invades through visceral pleura to involve diaphragm
- See comment and staging parameters
- Five lymph nodes, negative for neoplasm (0/5)
- Background bronchus is unremarkable
- Background lung shows mild nonspecific changes
- F) LYMPH NODES, LEVEL 11R, DISSECTION:
Two lymph nodes, negative for neoplasm (0/2)
- G) LYMPH NODES, 4R, DISSECTION:
Six lymph nodes, negative for neoplasm (0/6)

COMMENT

E) Although the previous biopsy showed moderately differentiated squamous carcinoma, the vast majority of the resection demonstrates poorly differentiated morphology.

LUNG CANCER STAGING PARAMETERS***

Patient name

[page 2 of 4]
TUMOR SITE

Right Lung - Lower Lobe

TUMOR SIZE

13 X 11.5 X 8.5 cm

TUMOR FOCALITY

Unifocal

MICROSCOPIC

HISTOLOGIC TYPE

Squamous cell carcinoma

HISTOLOGICAL GRADE

G3: (poorly differentiated) of G4

VISCERAL PLEURAL INVASION

Present

LYMPHATIC VASCULAR INVASION

Absent

TREATMENT EFFECT

Not applicable

TUMOR EXTENSION

Tumor extension identified

Tumor extension(s) identified: Diaphragm

MARGINS

Uninvolved by tumor

Distance of tumor from closest margin is 0.5 cm

PATHOLOGIC STAGING

EXTENT OF INVASION

pT3. (Tumor greater than 7 cm in greatest dimension, and tumor directly invades: diaphragm.

REGIONAL LYMPH NODES

pN0. (No regional lymph node metastasis)

Total nodes: 18

Total positive nodes: 0

N1 nodes: 8

N1 positive nodes: 0

N2 nodes: 10

N2 positive nodes: 0

N2 sites sampled:

Station 4: Lower paratracheal nodes

Station 7: Subcarinal nodes

DISTANT METASTASIS

pM0. (No distant metastasis)

PATHOLOGIC STAGE Summary

Final TNM: pT3N0M0

Stage: IIB

** The pathologic stage presumes no distant metastasis.

Attending Pathologist: [REDACTED]

CLINICAL INFORMATION

[REDACTED] with biopsy-proven squamous carcinoma [REDACTED]

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Lymph node biopsy, 4R

Received fresh labeled "4R lymph node" consists of five tan-pink 0.4 to 0.6 cm lymph node fragments entirely submitted on one chuck for frozen section diagnosis.

[page 3 of 4]
[REDACTED]

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Benign lymph node fragments" is rendered by [REDACTED].

B) SOURCE: Lymph node biopsy, level 7 subcarinal
Received fresh labeled "left 7 subcarinal lymph node" is a single 0.6 cm tan-pink lymph node entirely submitted on one chuck for frozen section diagnosis.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "One benign lymph node" is rendered by [REDACTED]

C) SOURCE: Lymph node biopsy, level 7
Received fresh labeled "level 7 lymph nodes" are 1, 4 cm lymph nodes. The smaller node is inked yellow and bisected and submitted along with representative of the largest node on chuck 1. The remainder of the larger node is submitted on chucks 2 and 3.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Two benign lymph nodes" is rendered by [REDACTED]

D) SOURCE: Lymph node biopsy, right level 11
The specimen is received labeled "level 11 lymph node R." It consists of a 1.5 x 1.2 x 0.7 cm maroon-tan apparent lymph node. It is bisected revealing gray-black anthracotic pigmentation on cut section. All tissue is entirely submitted in a single cassette.

[REDACTED]

E) SOURCE: Right lower lobe
Labeled "RT lower lobe" is a 927 gm, 18 x 14.5 x 10 cm stated left lower lobe. The pleura is maroon-pink. There is a 6.5 x 5 cm circular roughened area. Per direct conversation with the surgeon, this area represents tissue abutting diaphragm. This surface is inked yellow. The bronchial resection margin measures 3 x 1.3 cm and contains multiple silver surgical clips in a staple line. The staple line is removed, and the subadjacent tissue is inked blue. Located 2.5 cm from the bronchial resection margin is a 5 cm in length x 0.3 cm in width staple line composed of multiple silver surgical clips. The staple line is removed, and the subjacent tissue is inked black.

The specimen is serially sectioned revealing a 13 x 11.5 x 8.5 cm white-tan, focally softened and friable mass. The mass abuts the yellow-inked roughened area on the pleura indication tissue abutting diaphragm. It is located 2 cm from the bronchial resection margin and 3.5 cm from the black-inked staple line. The mass has circumscribed edges. It appears to involve adjacent bronchi.

The remaining lung parenchyma is red-maroon, soft and spongy. No additional discrete lesions or masses are identified. There are multiple gray-black peribronchial lymph nodes with anthracotic pigmentation. The hilar vessels appear patent.

Representative section including entire bronchial resection margin is submitted for frozen section diagnosis on one block.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Bronchial margin negative (grossly approximately 2 cm) negative by frozen section" is rendered by [REDACTED]

Summary of sections:
EFS1. Frozen section
2. Hilar vascular margins

[REDACTED]

[REDACTED]

[page 4 of 4]
- [REDACTED]
- 3,4. Mass focally abutting yellow-inked pleura
5. Mass with adjacent bronchus
6. Mass with adjacent lung parenchyma
7. Uninvolved lung parenchyma including black-inked staple line
8. One peribronchial lymph node quadriseected
9. Four peribronchial lymph nodes in toto
10. One peribronchial lymph node bisected

Note: Tissue is obtained for tumor banking protocol per [REDACTED]

[REDACTED]

F) SOURCE: Level 11 lymph node, right (additional)

Labeled "level 11 lymph node R additional" are two maroon-tan soft to rubbery apparent lymph nodes measuring 1.5 x 1.3 x 1 cm and 2.5 x 1.5 x 0.5 cm. All tissue is entirely submitted in four cassettes as follows:

- 1,2. One lymph node, quadriseected
- 3,4. Larger lymph node, bisected

G) SOURCE: Additional 4R lymph node, right

Labeled "additional 4R lymph node, right" are six apparent lymph nodes ranging from 1-2 cm in greatest dimension. The lymph nodes have focal gray-tan anthracotic pigmentation. The lymph nodes are entirely submitted as follows:

1. Four lymph nodes in toto
2. One lymph node, bisected
3. One lymph node, quadriseected

This case is accessioned in [REDACTED]

[REDACTED]

MICROSCOPIC

A-G) The microscopic appearance substantiates the diagnosis. Dictation by:

[REDACTED] transcribed by: [REDACTED]

[REDACTED]

Lab and Collection

GROSS AND MICROSCOPIC SURGICAL PANEL
Information

[REDACTED] Lab and Collection

Result History

GROSS AND MICROSCOPIC SURGICAL PANEL
Report

[REDACTED] er Result History

Lab Status

Order Complete [3]

[REDACTED]

Result Information

[REDACTED]

Source: NCI Genomic Data Commons file 09137087-4ee7-4720-a3b2-caa01a4d5747 (TCGA-56-8307.DD8A238F-F909-4B35-B6E5-B4B9D404D424.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).